Gene-level copy-number profile of tumor specimen TCGA-AG-3896-01A from TCGA case TCGA-AG-3896, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 85.0 years (31,046 days).
Specimen TCGA-AG-3896-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.7163a4f0-31f4-4faf-a275-20adbdfe88d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3896-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34863384-8a92-4ed0-8ddb-2e0df9076020

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,084; copy number 2: 30,771; copy number 3: 23,949; copy number 4: 1,938; copy number 5: 38; copy number 6: 65; copy number 7: 932; copy number 8: 32; copy number 11: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3896-01A-01D-1428-01): tumor purity 0.64, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,721,786–6,874,005, 3 genes: AC007012.1, RNU7-99P, RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,075 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:29,067,278–29,263,124, 1 gene, copy number 5 (within-gene range 1–5): KIF13B.
- chr8:29,110,573–29,798,492, 11 genes, copy number 5 (within-gene range 1–5): AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099.
- chr8:49,909,789–53,524,336, 35 genes, copy number 6 (within-gene range 3–6): SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4.
- chr8:64,587,763–65,843,331, 16 genes, copy number 5 (within-gene range 3–5): CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1.
- chr8:78,805,293–81,924,348, 72 genes, copy number 5–8 (broad region; genes not listed).
- chr13:18,467,172–78,617,328, 940 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,084. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
